Surgical pathology report (de-identified scan), TCGA case TCGA-NJ-A7XG, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Rush University, specimen TCGA-NJ-A7XG-01A (Primary Tumor).

[page 1 of 4]
ICD-O-3
Adenocarcinoma NOS 8140/3
Site Lung, upper lobe C34.1
JW 10/4/13

Final

Clinical Data Repository* This report may not match the original report format

REPORT DATE:

FINAL DIAGNOSIS

A. (Level 4R lymph node; excision):

One lymph node, negative for carcinoma.

B. (AP window node level 5; excision):

One lymph node, negative for carcinoma.

C. (Level 6 lymph node; excision):

One lymph node, negative for carcinoma.

D. (Left lung; pneumonectomy):

Invasive moderately differentiated adenocarcinoma, present in the upper lobe and measuring 10 cm, with extensive lymphovascular invasion, extending into the parietal pleura.

Multiple tumor nodules are identified in the left lower lobe.

Metastatic carcinoma in 10 of 21 peribronchial lymph nodes.

Margins of resection are free.

Stage: pT4N1

See note.

Attending Pathologist:

* Electronically signed Pathology

Resident:

INTRAOPERATIVE CONSULTATION

A. FROZEN:LEVEL 4R LYMPH NODE: Negative for malignancy. (A91, tp, smear)

Intraoperative consultation pathologist

Intraoperative consultation resident

[page 2 of 4]
D. LEFT LUNG. FROZEN ON MARGIN: Negative for malignancy. (D91)

Intraoperative consultation pathologist
Intraoperative consultation resident

NOTE

An elastic stain has been evaluated; findings support the above diagnosis.

Lung Cancer Summary

Specimen type: Left lung

Procedure: Pneumectomy

Specimen integrity: Intact

Tumor location: Left upper lobe

Tumor focality: Multifocal; separate tumor nodules in different lobes

Tumor size: 10 x 4 x 2.5 cm (gross measurement)

Histologic type: Adenocarcinoma

Histologic grade: Grade 2

Treatment effect: Not applicable

Status of margins:

Bronchial: Negative

Vascular: Negative

Parenchymal: Not applicable

Pleural: Tumor infiltrates into parietal pleura

Visceral/Parietal pleural invasion: Present

Lymphatic vascular invasion: Present

Lymph node status: Positive (Peribronchial)

Extension into other structures: Absent

Non-neoplastic pathology: Absent

[page 3 of 4]
TMN stage: pT4N1

GROSS DESCRIPTION

A. The specimen is labeled level 4R lymph node. Received fresh for frozen section is a piece of soft, black tissue (0.5 x 0.2 x 0.2 cm). Touch preps and smear are obtained and the specimen is submitted entirely for frozen section with the remnant placed in cassette A91.

B. The specimen is labeled AP window node level V. Received without fixative is a 1.6 x 1.0 x 0.5 cm anthracotic lymph node. The entire specimen is submitted in cassette B1.

C. The specimen is labeled level VI lymph node. Received without fixative is a 1.3 x 1.1 x 0.6 cm anthracotic lymph node. The specimen is bisected and entirely submitted in cassette C1.

D. The specimen is labeled left lung. Received fresh for frozen analysis is a 16 x 14 x 12 cm left lung. The pleural surface shows two areas of adhesions in the left upper lobe. The first area measures 7 x 7 cm and has attached fibroadipose tissue, is more lateral and posterior. The second adhesion area measures 7 x 2 cm and is located anteriorly; both areas are inked blue and the specimen is serially sectioned to reveal in the left upper lobe a 10 x 4 x 2.5 cm white-tan mass with areas of necrosis. The mass appears to invade through the pleura in both areas of adhesions. The mass is also present 1 cm from the bronchial margin and 1 cm from the vascular margins. There is only a rim of unremarkable lung tissue in the left upper lobe. The left lower lobe shows multiple nodules, in a miliary pattern, throughout the lung, ranging in size from 2 to 8 mm; those nodules are confluent the superior portion of the left lower lobe. No normal lung tissue is identified in this lobe. The hilar area shows multiple lymph nodes, ranging in size from 2 to 0.5 cm. The mass does not appear to cross the fissure. The bronchial margin is submitted for frozen analysis with the remnants placed in cassette D91. The remainder of the specimen is submitted as follows: D1 bronchial vascular margin, D2 multiple lymph nodes, D3 one lymph node serially sectioned, D4 one lymph node bisected, D5 one lymph node bisected, D6 one intact lymph node, D7 - one lymph node bisected, D8 and D9 mass and underlying large pleural adhesion area, D10 mass and underlying small pleural adhesion area, D11 mass and adjacent pulmonary artery, D12 - mass, D13 and D14 small nodules from the left lower lobe, D15 confluent nodules from the left lower lobe, D16 left upper lobe and left lower lobe junction, D17 unremarkable lung from the left lower lobe, D18 multiple lymph nodes, D19 one lymph node bisected.

SPECIMEN(S) RECEIVED

[page 4 of 4]
A: FROZEN:LEVEL 4R LYMPH NODE
B: AP WINDOW NODE LEVEL 5
C: LEVEL 6 LYMPH NODE
D: LEFT LUNG. FROZEN ON MARGIN

* The above listed tests (if any) were developed and the performance characteristics determined by . These tests have not been cleared or approved for commercial use by the U.S. Food and Drug Administration. The FDA has determined that FDA review is not required for such in-house assays. (21 CFR 809.30(e))

OPERATIVE INFORMATION

DIAGNOSIS: LUNG CA; PROCEDURE: BRONCHOSCOPY AND MEDIASTINOSCOPY,
THORACOSCOPY
VIDEO ASSISTED

ICD-9(s): 162.3

CPT(s): A; 88305, 88331, 88333, 88334

B; 88305

C; 88305

D; 88309, 88331, 88313

The attending pathologist was physically present when this specimen was diagnosed, and actively participated in all key decisions.

Source: NCI Genomic Data Commons file 2f4abaf5-ce78-42df-b379-5f54e1a05440 (TCGA-NJ-A7XG.8EFDF414-12F3-4DF8-BB21-9E8876B727E8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).